Somatic mutation profile of tumor specimen TCGA-E7-A7PW-01A (aliquot TCGA-E7-A7PW-01A-11D-A34U-08) from TCGA case TCGA-E7-A7PW, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 63.1 years (23,057 days).
Specimen TCGA-E7-A7PW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 131960c9-2b20-4c9f-8c70-cbcf7625988b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A7PW-10A (Blood Derived Normal), aliquot TCGA-E7-A7PW-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c4900ca-f288-4603-8278-27c65ccdf480

The open-access MAF lists 98 somatic variants for this specimen: 63 protein-altering or splice-affecting, 28 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 28, Nonsense Mutation 4, Intron 3, Splice Site 2, In Frame Del 2, 3'UTR 2, Splice Region 1, 5'UTR 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGR2 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs864622273, CM1512080, COSV54346929; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALPK2 | c.5093C>T p.S1698L | Missense Mutation (SNP) | VAF 75/138 reads (54%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs375605840, COSV64490108; called by muse, mutect2, varscan2
- ARHGAP45 | c.2474C>T p.S825L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as rs757497966, COSV57431686, COSV57435225; called by muse, mutect2, varscan2
- ATP13A2 | c.2348G>T p.R783L | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as COSV58700488; called by muse, mutect2, varscan2
- BIRC6 | c.13456G>C p.E4486Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.076); catalogued as COSV70199154; called by muse, mutect2, varscan2
- BLVRA | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV55514092; called by muse, mutect2, varscan2
- BMPR2 | c.2221C>T p.Q741* | Nonsense Mutation (SNP) | VAF 17/89 reads (19%) | catalogued as COSV101001500; called by muse, mutect2, varscan2
- BSN | c.10126G>A p.E3376K | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56517794; called by muse, mutect2, varscan2
- C19orf54 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774453848, COSV54574809; called by muse, mutect2, varscan2
- C8orf34 | c.639C>A p.N213K | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs537514672, COSV61379577; called by muse, mutect2, varscan2
- CEACAM7 | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0.022); catalogued as COSV50072897; called by muse, mutect2, varscan2
- CELSR2 | c.5599G>C p.E1867Q | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.571); catalogued as COSV54771640; called by muse, mutect2
- CEP170 | c.1409G>A p.R470K | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.97); catalogued as COSV60508978; called by muse, mutect2, varscan2
- CHD2 | c.2660C>T p.S887F | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67709267; called by muse, mutect2, varscan2
- DDX27 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs780544787, COSV65629684; called by muse, mutect2, varscan2
- DNAAF2 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100023733, COSV53567860; called by muse, mutect2
- DOCK4 | c.5834A>C p.N1945T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.027); catalogued as COSV70236751; called by muse, mutect2, varscan2
- DYNC1H1 | c.8087C>G p.S2696* | Nonsense Mutation (SNP) | VAF 64/121 reads (53%) | catalogued as COSV100794924; called by muse, mutect2, varscan2
- EFL1 | c.1105A>G p.I369V | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs372574913; called by muse, mutect2, varscan2
- GARRE1 | c.2869C>A p.P957T | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55099200; called by muse, mutect2
- GSS | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs957943815, COSV53624636; called by muse, mutect2, varscan2
- GSTM5 | c.457-1G>T p.X153_splice | Splice Site (SNP) | VAF 124/207 reads (60%) | catalogued as COSV56657036, COSV56657991; called by muse, mutect2, varscan2
- HASPIN | c.1498C>G p.Q500E | Missense Mutation (SNP) | VAF 64/76 reads (84%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1445703139, COSV53993757; called by muse, mutect2, varscan2
- IFT43 | c.527G>T p.W176L (on ENST00000314067 / NM_001102564.3; = p.W181L on NM_052873.3) | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53138569; called by muse, mutect2, varscan2
- IK | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101341786; called by muse, mutect2, varscan2
- IL16 | c.2771C>T p.P924L (on ENST00000302987 / NM_172217.5; = p.P223L on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV57263539; called by muse, mutect2, varscan2
- IL22 | c.475G>T p.G159* | Nonsense Mutation (SNP) | VAF 818/1076 reads (76%) | catalogued as COSV100048851; called by muse, mutect2, varscan2
- IMPG2 | c.1621C>A p.P541T | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51978134; called by muse, mutect2, varscan2
- INTS5 | c.2713G>C p.E905Q | Missense Mutation (SNP) | VAF 74/118 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57950389, COSV57951499; called by muse, mutect2, varscan2
- LRP2 | c.8970G>C p.R2990S | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.678); catalogued as COSV55552873; called by muse, mutect2, varscan2
- MAGEB16 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV67873921; called by muse, mutect2, varscan2
- METTL5 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53626520; called by muse, mutect2, varscan2
- NBEA | c.3793G>A p.E1265K | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.073); catalogued as COSV59783417; called by muse, mutect2, varscan2
- OR10A7 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 29/125 reads (23%) | catalogued as COSV100406566; called by muse, mutect2, varscan2
- OR52B4 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs766612100, COSV68768781; called by muse, mutect2, varscan2
- OR52E4 | c.451G>T p.V151F | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs765781520, COSV57624749; called by muse, mutect2, varscan2
- PLXNB1 | c.5107G>C p.V1703L | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV56489559; called by muse, mutect2, varscan2
- POGK | c.1816G>T p.A606S | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.01); catalogued as COSV63311576; called by muse, mutect2
- PPARG | c.503G>A p.R168K (on ENST00000287820 / NM_015869.5; = p.R138K on NM_005037.7) | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55142361; called by muse, mutect2, varscan2
- PRPF40A | c.540A>G p.K180= | Splice Region (SNP) | VAF 41/145 reads (28%) | catalogued as rs759028336, COSV62957338; called by muse, mutect2, varscan2
- PSMD3 | c.225C>G p.I75M | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV52857537; called by muse, mutect2, varscan2
- RASAL1 | c.74G>A p.S25N | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV55655958; called by muse, mutect2, varscan2
- RB1 | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 103/123 reads (84%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as CD941772, CM0910366, COSV57296743, COSV57307114; called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.281); catalogued as COSV58242198; called by muse, mutect2, varscan2
- RYR2 | c.12373G>A p.V4125I | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.153); catalogued as rs775417996, COSV63658123, COSV63663747, COSV63724087; called by muse, mutect2, varscan2
- SLC16A10 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as rs145047809, COSV100785624; called by muse, varscan2
- SLC16A6 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as rs1555749368, COSV59177380; called by muse, mutect2, varscan2
- SLCO4A1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs1447598529, COSV53890824; called by muse, mutect2, varscan2
- SPHKAP | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100764259, COSV60878584; called by muse, mutect2, varscan2
- SPN | c.365C>A p.A122E | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV64070401; called by muse, mutect2, varscan2
- SYNE1 | c.23000A>G p.K7667R (on ENST00000367255 / NM_182961.4; = p.K7596R on NM_033071.3) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV54979371; called by muse, mutect2, varscan2
- TENM3 | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1257428948, COSV69310298; called by muse, mutect2
- TENM3 | c.6156A>C p.K2052N | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV69307906; called by muse, mutect2
- TMPRSS15 | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53039719; called by muse, mutect2, varscan2
- TRAPPC12 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.243); catalogued as COSV100160533; called by muse, mutect2, varscan2
- UNC79 | c.1350C>G p.I450M (on ENST00000393151 / NM_001346218.2; = p.I273M on NM_020818.5) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99827942; called by muse, mutect2, varscan2
- VPS54 | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as COSV55440734; called by muse, mutect2, varscan2
- ZNF184 | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53004273; called by muse, mutect2, varscan2
- ZNF530 | c.748C>G p.Q250E | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.301); catalogued as COSV60531541; called by muse, mutect2
- GLMP | c.1129_1146del p.A377_G382del | In Frame Del (DEL) | VAF 42/179 reads (23%) | called by mutect2, pindel, varscan2
- LCAT | c.1018_1026del p.G340_G342del | In Frame Del (DEL) | VAF 25/154 reads (16%) | called by mutect2, pindel, varscan2
- TAOK3 | c.2536-37_2547del p.X846_splice | Splice Site (DEL) | VAF 58/408 reads (14%) | called by mutect2, pindel
- TRIM47 | c.986_998del p.S329Cfs*7 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel
- ANK2 | c.11838G>A p.K3946= | Silent (SNP) | VAF 52/136 reads (38%) | catalogued as COSV52150225, COSV52160816; called by muse, mutect2, varscan2
- ARHGAP26 | c.2094C>G p.P698= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV50829235, COSV50835336; called by muse, mutect2, varscan2
- BOD1L1 | c.5220G>A p.V1740= | Silent (SNP) | VAF 101/185 reads (55%) | catalogued as COSV50013082; called by muse, mutect2, varscan2
- CNNM3 | c.1029G>A p.Q343= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs1327790450, COSV59709181; called by muse, mutect2, varscan2
- CYP1A1 | c.789G>A p.Q263= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs1219303815, COSV65697197; called by muse, mutect2, varscan2
- DRD2 | c.228C>T p.L76= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs200084134, COSV60757834; called by muse, mutect2, varscan2
- ECM2 | c.1174C>T p.L392= | Silent (SNP) | VAF 33/51 reads (65%) | catalogued as COSV60739099; called by muse, mutect2, varscan2
- FAM186B | c.1359C>G p.L453= | Silent (SNP) | VAF 92/99 reads (93%) | catalogued as COSV57721491, COSV99219909; called by muse, mutect2, varscan2
- GAS2L2 | c.1509C>A p.I503= | Silent (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- GPR75 | c.927C>T p.I309= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV61827232; called by muse, mutect2, varscan2
- ITGA4 | c.2604T>C p.S868= | Silent (SNP) | VAF 72/130 reads (55%) | catalogued as COSV67897280; called by muse, mutect2, varscan2
- MYADM | c.456C>T p.A152= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV61239377; called by muse, mutect2, varscan2
- OR6F1 | c.132T>C p.A44= | Silent (SNP) | VAF 9/254 reads (4%) | catalogued as COSV57467790; called by muse, mutect2
- ORM2 | c.384G>A p.L128= | Silent (SNP) | VAF 54/86 reads (63%) | catalogued as COSV56336829; called by muse, mutect2, varscan2
- PDE3A | c.669C>T p.T223= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as COSV62972777; called by muse, mutect2
- PURB | c.660G>A p.P220= | Silent (SNP) | VAF 56/165 reads (34%) | catalogued as rs748153717, COSV67480324; called by muse, mutect2, varscan2
- QSER1 | c.93G>A p.Q31= (on ENST00000399302; = p.Q160= on NM_001076786.3) | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as rs745833150, COSV67900543; called by muse, mutect2, varscan2
- RNF145 | c.1578G>A p.T526= (on ENST00000424310 / NM_001199383.2; = p.T554= on NM_144726.2) | Silent (SNP) | VAF 67/77 reads (87%) | catalogued as rs780679803, COSV50866303; called by muse, mutect2, varscan2
- TAF4B | c.1452G>A p.V484= | Silent (SNP) | VAF 132/149 reads (89%) | catalogued as COSV52303654; called by muse, mutect2, varscan2
- TCTN2 | c.255G>A p.V85= | Silent (SNP) | VAF 31/179 reads (17%) | catalogued as COSV57632942; called by muse, mutect2, varscan2
- TNR | c.3159C>A p.T1053= | Silent (SNP) | VAF 11/141 reads (8%) | catalogued as COSV54885454; called by muse, mutect2
- TSSK2 | c.360C>T p.L120= | Silent (SNP) | VAF 57/69 reads (83%) | catalogued as COSV52816958; called by muse, mutect2, varscan2
- TUBB | c.789C>G p.L263= | Silent (SNP) | VAF 6/122 reads (5%) | catalogued as COSV58357647; called by muse, mutect2
- UCK2 | c.171C>T p.V57= | Silent (SNP) | VAF 63/126 reads (50%) | catalogued as COSV63315311; called by muse, mutect2, varscan2
- USH2A | c.15282G>A p.P5094= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as rs754800723, COSV56360800, COSV56368419; called by muse, mutect2, varscan2
- VPS54 | c.639G>T p.L213= | Silent (SNP) | VAF 43/129 reads (33%) | catalogued as COSV55440746; called by muse, mutect2, varscan2
- WDR37 | c.159G>T p.S53= | Silent (SNP) | VAF 67/226 reads (30%) | catalogued as COSV54128768; called by muse, mutect2, varscan2
- ZNF516 | c.3471G>A p.V1157= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV71587011; called by muse, mutect2, varscan2
- COPB2 | chr3:139355759 A>C | 3'Flank (SNP) | VAF 11/97 reads (11%) | catalogued as COSV60349894; called by muse, mutect2
- PAQR6 | c.760+61G>A | Intron (SNP) | VAF 16/58 reads (28%) | catalogued as COSV52745191; called by muse, mutect2, varscan2
- PRRC2B | c.6226-890C>G | Intron (SNP) | VAF 112/186 reads (60%) | catalogued as COSV100261000; called by muse, mutect2, varscan2
- PSD3 | c.2176-28105C>G | Intron (SNP) | VAF 111/130 reads (85%) | catalogued as COSV54071226; called by muse, mutect2, varscan2
- SLC37A3 | c.*12G>A | 3'UTR (SNP) | VAF 48/144 reads (33%) | catalogued as rs760138390, COSV58264821; called by muse, mutect2, varscan2
- TTLL4 | c.-1C>G | 5'UTR (SNP) | VAF 4/77 reads (5%) | catalogued as COSV99293317; called by muse, mutect2
- WSB2 | c.*2C>T | 3'UTR (SNP) | VAF 24/376 reads (6%) | catalogued as rs781357348, COSV99969884; called by muse, mutect2
